TARGET case TARGET-20-PAUVSU — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79c4e658-345c-44af-b58e-7d12f897b7e4

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 14 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.6 years (5,339 days); Year of diagnosis: 2012; Days to last follow up: 2,688 days (7.4 years).
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0631.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 2,688 days (7.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,688; Year of follow up: 2019.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 25.2 ×10³/µL; Blast Count 44%; Bone Marrow blast count 90%.

Biospecimens (1 sample)
- Sample TARGET-20-PAUVSU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- First Event: Censored
- Overall Survival Time in Days: 2688
- WBC at Diagnosis: 25.2
- Bone marrow leukemic blast percentage (%): 90
- Peripheral blasts (%): 44
- Chloroma: No
- FAB Category: M3
- Cytogenetic Complexity: 2
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XX,t(15;17)(q24;q21)[2]/46,idem,t(9;22)(q34;q11.2)[18]
- SCT in 1st CR: No
